Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6571, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6571-01A (Primary Tumor).

[page 1 of 2]
			Formatted Path Report
			LARGE INTESTINE TISSUE CHECKLIST
			Specimen type: Excision of tumor
			Specimen size: Not specified
			Tumor site: Rectum
			Tumor size: 4 x 5 x 1.5 cm
			Tumor features: None specified
			Histologic type: Adenocarcinoma
			Histologic grade: Moderately differentiated
			Tumor extent: Subserosa
			Lymph nodes: 0/2 positive for metastasis (Regional 0/2)
			Margins: Not specified
			Evidence of neo-adjuvant treatment: Not specified
			Additional pathologic findings: Not specified
			Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file bbf7e455-0168-409e-9b24-e87f3642aacc (TCGA-F5-6571.8414BE9C-917B-4487-84F9-A7593355C36D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).